Surgical pathology report (de-identified scan), TCGA case TCGA-14-0783, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0783-01B (Primary Tumor).

[page 1 of 2]
==Section 1 of 1: Anatomic Pathology Report

Patient: [REDACTED] Accession Number: [REDACTED]
Age: [REDACTED] Sex: F DOB: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT FRONTAL LOBE LESION, BIOPSY, FS1A: GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT FRONTAL LOBE LESION, EXCISION: GLIOBLASTOMA MULTIFORME.

Verified:

(Electronic Signature)

SPECIMEN:

1. Left frontal brain lesion.
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Left frontal craniotomy for tumor.

PREOPERATIVE DIAGNOSIS: Left frontal brain lesion.

GROSS DESCRIPTION:

The specimen is received in two parts, each labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation, labeled "left frontal brain lesion." The specimen consists of multiple fragments of tan-red and yellow tissue measuring 2.0 x 1.3 x 0.3 cm in aggregate. A representative section is submitted for frozen section and the remaining cryoblock is submitted in cassette "FS1A." The remaining tissue is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "left frontal brain lesion." The specimen consists of two irregularly-shaped, tan-pink fragments of tissue with adherent blood clot, measuring 3.0 x 1.8 x 1.0 cm in aggregate. There are focal areas of yellow discoloration. The specimen is entirely submitted in cassettes "2A" through "2C."

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT FRONTAL BRAIN LESION (FROZEN SECTION): HIGH GRADE GLIOMA, FAVOR GLIOBLASTOMA MULTIFORME.

Pathologist:

TISSUE COMMITTEE CODE:

1

Resident:

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.1

[page 2 of 2]
Section 1 of 1: Anatomic Pathology Report

Patient: [redacted]
Age: [redacted] Sex: F DOB: [redacted]
Patient Number: [redacted]
Financial Number: [redacted]
Room/Bed: [redacted] PT: [redacted]
Admitting Physician: [redacted]
Ordering Physician: [redacted]

Accession Number: [redacted]
Date Collected: [redacted]
Date Received: [redacted]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT FRONTAL LOBE LESION, BIOPSY, FS1A: GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT FRONTAL LOBE LESION, EXCISION: GLIOBLASTOMA MULTIFORME.

Verified:

(Electronic Signature)

SPECIMEN:

1. Left frontal brain lesion.
2. Left frontal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Left frontal craniotomy for tumor.

PREOPERATIVE DIAGNOSIS: Left frontal brain lesion.

GROSS DESCRIPTION:

The specimen is received in two parts, each labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation, labeled "left frontal brain lesion." The specimen consists of multiple fragments of tan-red and yellow tissue measuring 2.0 x 1.3 x 0.3 cm in aggregate. A representative section is submitted for frozen section and the remaining cryoblock is submitted in cassette "FS1A." The remaining tissue is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "left frontal brain lesion." The specimen consists of two irregularly-shaped, tan-pink fragments of tissue with adherent blood clot, measuring 3.0 x 1.8 x 1.0 cm in aggregate. There are focal areas of yellow discoloration. The specimen is entirely submitted in cassettes "2A" through "2C."

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT FRONTAL BRAIN LESION (FROZEN SECTION): HIGH GRADE GLIOMA, FAVOR GLIOBLASTOMA MULTIFORME.

Pathologist:

TISSUE COMMITTEE CODE:

1

Resident:

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.1

Source: NCI Genomic Data Commons file 840ad805-4b2e-45f0-b135-04a3992d8a47 (TCGA-14-0783.4E98F589-4526-40FF-8424-266A40FBDFFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).